Gene-level copy-number profile of tumor specimen TCGA-77-8007-01A from TCGA case TCGA-77-8007, project TCGA-LUSC (Lung Squamous Cell Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IIB; Age at diagnosis: 68.7 years (25,102 days).
Specimen TCGA-77-8007-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-LUSC.f7937e33-794c-4c47-a4ac-ceeee65c066e.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-77-8007-11A (solid tissue normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 810 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/ff6e414b-f9d1-43c0-a766-d1ed47b7da7b

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 3,452; copy number 2: 33,673; copy number 3: 17,152; copy number 4: 2,705; copy number 5: 395; copy number 6: 992; copy number 7: 646; copy number 8: 381; copy number 9: 163; copy number 10: 32; copy number 11: 81; copy number 12: 16; copy number 13: 52; copy number 16: 73.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-77-8007-01A-11D-2183-01): tumor purity 0.21, ploidy 3.23, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 2,831 genes in 10 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:120,552,481–121,809,962, 22 genes, copy number 5–8 (within-gene range 2–8): AC073257.1, Y_RNA, AC018866.1, GLI2, AC017033.1, Y_RNA, AC067960.1, AC079988.1, TFCP2L1, RPS17P7, CLASP1, AC012447.1, RNU4ATAC, Y_RNA, NIFK-AS1, RPL12P15, AC018737.2, NPM1P32, NIFK, TSN, AC018737.1, LINC01823.
- chr4:9,771,153–10,054,936, 1 gene, copy number 5 (within-gene range 4–5): SLC2A9.
- chr4:9,922,814–37,449,463, 255 genes, copy number 5 (broad region; genes not listed).
- chr4:37,454,698–37,476,401, 1 gene, copy number 5 (within-gene range 4–5): AC022463.1.
- chr4:43,340,875–46,475,230, 29 genes, copy number 5 (within-gene range 2–5): AC097451.1, AC098590.2, AC098590.1, LINC02383, AC114774.1, RN7SL691P, AC080132.1, RN7SL193P, NDUFB4P12, AC114757.1, LINC02475, KCTD8, AC093852.1, YIPF7, GUF1, GNPDA2, AC096586.2, AC096586.1, AC093755.1, PRDX4P1, AC108467.2, AC108467.1, THAP12P9, AC108043.1, RNU6-931P, RN7SKP199, GABRG1, AC104072.1, GABRA2.
- chr4:54,603,211–60,922,684, 96 genes, copy number 5 (broad region; genes not listed).
- chr5:58,198–45,895,970, 710 genes, copy number 6 (broad region; genes not listed).
- chr7:49,773,638–50,159,256, 6 genes, copy number 7 (within-gene range 3–7): VWC2, ZPBP, GNL2P1, AC034148.1, SPATA48, AC020743.1.
- chr7:107,808,734–123,230,741, 178 genes, copy number 7–16 (broad region; genes not listed).
- chr8:46,549,089–145,066,685, 1,533 genes, copy number 6–12 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 1,031. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
